Gene-level copy-number profile of tumor specimen CDDP-A8B5-TTP1-C from CDDP_EAGLE case CDDP-A8B5, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65 years.
Specimen CDDP-A8B5-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dbab4181-ac3d-4375-b9fa-cc31e45b98f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-A8B5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/fb087e2e-d552-44d6-a90b-d5f0ea4f9ae0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 860; copy number 2: 7,679; copy number 3: 22,171; copy number 4: 15,808; copy number 5: 3,620; copy number 6: 4,476; copy number 7: 1,368; copy number 8: 413; copy number 9: 2,362; copy number 11: 95; copy number 12: 47.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:35,021,749–35,085,060, 5 genes (within-gene range 0–3): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,285 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 7 (within-gene range 3–7): AL627309.1.
- chr1:131,025–522,928, 20 genes, copy number 7: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:239,972,787–240,475,187, 7 genes, copy number 8 (within-gene range 6–8): AL356361.1, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2.
- chr3:83,937,045–87,324,723, 22 genes, copy number 7–9: SRRM1P2, LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25.
- chr3:103,159,960–108,953,879, 53 genes, copy number 8: RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1, ALCAM, CBLB, AC079382.1, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C.
- chr3:149,517,235–149,736,714, 1 gene, copy number 7 (within-gene range 3–7): WWTR1.
- chr3:149,648,997–150,050,788, 13 genes, copy number 7 (within-gene range 5–7): WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24.
- chr5:58,198–45,895,970, 679 genes, copy number 7 (broad region; genes not listed).
- chr7:37,032–64,030,105, 1,095 genes, copy number 7–12 (broad region; genes not listed).
- chr8:8,011,782–8,024,652, 2 genes, copy number 9: FAM90A11P, FAM90A24P.
- chr8:12,064,389–12,115,516, 4 genes, copy number 7–11: DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr8:54,420,468–145,066,685, 1,372 genes, copy number 9 (broad region; genes not listed).
- chr10:29,289,061–30,115,494, 11 genes, copy number 7: LYZL1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P, AL353093.1, JCAD.
- chr11:68,754,620–69,775,341, 29 genes, copy number 11: CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr14:34,561,093–34,630,160, 1 gene, copy number 7 (within-gene range 6–7): SNX6.
- chr14:34,659,564–37,596,059, 74 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr17:20,814,620–27,241,661, 71 genes, copy number 11–12 (broad region; genes not listed).
- chr20:87,250–31,723,989, 573 genes, copy number 7–12 (broad region; genes not listed).
- chr20:31,944,337–32,050,705, 7 genes, copy number 9 (within-gene range 3–9): PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482.
- chr20:35,002,404–37,241,619, 77 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:49,113,339–49,484,297, 13 genes, copy number 8: STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.
- chr20:49,972,106–50,479,991, 16 genes, copy number 8: RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2.
- chr20:53,255,979–53,827,297, 10 genes, copy number 8 (within-gene range 3–8): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1.
- chr20:54,475,593–54,651,169, 1 gene, copy number 8: DOK5.
- chr20:57,105,741–62,776,996, 133 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
